TCGA case TCGA-EK-A2RL — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/61eb08d0-ea01-45e7-884b-ac3d6070172a

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 32 years; Vital status: Dead; Days to death: 1,453 days (4.0 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Adenocarcinoma, endocervical type (the primary disease): ICD-O-3 morphology code: 8384/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 33.0 years (12,047 days); Year of diagnosis: 2009; Method of diagnosis: Biopsy; AJCC pathologic T: T1b1; AJCC pathologic N: N1; AJCC pathologic M: MX; FIGO stage: Stage IB; FIGO staging edition year: 1988; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Uterus.
   Pathology details: Consistent pathology review: Yes; Lymph nodes tested: 33; Lymphatic invasion present: No.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Days to treatment start: 912 days (2.5 years); Days to treatment end: 968 days (2.7 years); Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Adenocarcinoma, endocervical type), site: Cervix uteri. Age at diagnosis: 36.1 years (13,190 days); Days to diagnosis: 1,143 days (3.1 years); Prior treatment: Yes.

Follow-up (5 entries)
- Day 24 (preoperative): ECOG performance status: 0.
- Day 29 (preoperative): ECOG performance status: 0.
- Days to follow up: 721 days (2.0 years); Disease response: Tumor Free.
- Day 1,143 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Cervix uteri; Days to recurrence: 1,143 days (3.1 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,453 days (4.0 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 89 kg; Height: 154 cm; BMI: 37.5.
- Timepoint category: Prior to Diagnosis; Hysterectomy type: Radical Hysterectomy.

Exposures
- Exposure type: Tobacco.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EK-A2RL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 140 mg.
  Slide TCGA-EK-A2RL-01A-01-TS1: Section location: Top; Percent tumor cells: 73; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 25; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 20.
- Sample TCGA-EK-A2RL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Cervical; Histologic diagnosis: Endocervical Type of Adenocarcinoma; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: biopsy and endocervical curettage; Lymph nodes examined: Yes; Lymphovascular invasion: Absent; Corpus involvement: Present; Days to ct scan ab pelvis: 20.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Cause of death: Cervical Cancer.
- Drug treatment: Pharmaceutical therapy drug name: Taxol; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,453 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,453 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,143 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EK-A2RL-01A-11D-A18H-01): tumor purity 0.91, ploidy 2.08, whole-genome doublings 0.
